MMRF case MMRF_2173 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/669ad8f2-5339-49b3-a885-ef00d3966be1

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 75 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 75.2 years (27,451 days); ISS stage: II; Days to last known disease status: 902 days (2.5 years); Days to last follow up: 902 days (2.5 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 15 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -7 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.495 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 369 mg/dL; Immunoglobulin G 2.08 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.04 g/L; Beta 2 Microglobulin 4.62 µg/mL; Lactate Dehydrogenase 6.53 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 238 ×10⁹/L; Creatinine 168 µmol/L; Blood Urea Nitrogen 14.3 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 4.9 mmol/L; C-Reactive Protein 2.2 mg/dL.
- Day 96 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.319 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 115 mg/dL; Creatinine 124 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.13 mmol/L; Albumin 33 g/L; Total Protein 5.5 g/dL; Glucose 6.27 mmol/L.
- Day 163 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.361 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 49.4 mg/dL; Hemoglobin 7.32 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 6.3 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.25 mmol/L; Albumin 34 g/L; Total Protein 5.9 g/dL; Glucose 16.6 mmol/L.
- Day 274 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.103 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 21.7 mg/dL; Hemoglobin 8 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 6.3 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.38 mmol/L; Albumin 35 g/L; Total Protein 6.6 g/dL; Glucose 13.5 mmol/L.
- Day 338 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.093 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 15.7 mg/dL; Hemoglobin 8.18 mmol/L; Leukocytes 9 ×10⁹/L; Absolute Neutrophil 8.5 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.6 g/dL; Glucose 12 mmol/L.
- Day 443 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.515 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 17 mg/dL; Hemoglobin 8.43 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 5.9 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 5.6 g/dL; Glucose 8.25 mmol/L.
- Day 527 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.823 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 16.5 mg/dL; Hemoglobin 8.37 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 5.5 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 5.7 g/dL; Glucose 6.71 mmol/L.
- Day 625 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.854 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 15.7 mg/dL; Hemoglobin 8.25 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 5.5 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 120 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.18 mmol/L; Albumin 39 g/L; Total Protein 5.7 g/dL; Glucose 7.37 mmol/L.
- Day 723 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.854 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 14.7 mg/dL; Hemoglobin 8.68 mmol/L; Leukocytes 8.7 ×10⁹/L; Absolute Neutrophil 6.6 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 113 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 5.9 g/dL; Glucose 4.18 mmol/L.
- Day 793 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 15.6 mg/dL; Hemoglobin 8.87 mmol/L; Leukocytes 11.5 ×10⁹/L; Absolute Neutrophil 9.7 ×10⁹/L; Platelets 232 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 9.13 mmol/L.
- Day 902 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 14.2 mg/dL; Hemoglobin 8.49 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 5.7 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 113 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.15 mmol/L; Albumin 36 g/L; Total Protein 6.6 g/dL; Glucose 9.46 mmol/L.

Other clinical attributes
- Day -7: Weight: 58 kg; Height: 121 cm.

Biospecimens (2 samples)
- Sample MMRF_2173_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -7 days.
- Sample MMRF_2173_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -7 days.
